Somatic mutation profile of tumor specimen TCGA-AK-3447-01A (aliquot TCGA-AK-3447-01A-01W-0886-08) from TCGA case TCGA-AK-3447, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 84.0 years (30,676 days).
Specimen TCGA-AK-3447-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57662bc5-57f4-423a-9a6e-b9c187ff3eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3447-10A (Blood Derived Normal), aliquot TCGA-AK-3447-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f215029b-4153-4b56-b028-63ea47908fd9

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 21, Silent 17, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA7 | c.5596C>T p.H1866Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV54026805; called by muse, mutect2, varscan2
- ADAMTS18 | c.3025C>T p.R1009* | Nonsense Mutation (SNP) | VAF 158/315 reads (50%) | catalogued as rs751029682, COSV51402842; called by muse, mutect2, varscan2
- ATRX | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.327); catalogued as rs1557139920, COSV64874006; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1H | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61986905; called by muse, varscan2
- DSP | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 84/165 reads (51%) | catalogued as COSV65791735; called by muse, mutect2, varscan2
- EHBP1L1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769994697, COSV58572151; called by muse, mutect2, varscan2
- FRRS1L | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs773672601, COSV73746469; called by muse, mutect2, varscan2
- FSTL4 | c.1177+1G>T p.X393_splice | Splice Site (SNP) | VAF 72/302 reads (24%) | catalogued as COSV54767343; called by muse, mutect2, varscan2
- HIVEP3 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1275795270, COSV56012695; called by muse, mutect2
- ITIH4 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56572663; called by muse, mutect2, varscan2
- KLHDC10 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59050747; called by muse, mutect2, varscan2
- LIAS | c.347A>C p.D116A (on ENST00000261434 / NM_001363700.2; = p.D219A on NM_006859.4) | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV54695345; called by muse, mutect2, varscan2
- MAGEA10 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV54883496; called by muse, mutect2
- MED27 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV52599394; called by muse, mutect2
- MINAR1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV59581837; called by muse, mutect2
- MINAR1 | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV100548571, COSV59581851; called by muse, mutect2
- NAA15 | c.1394G>T p.C465F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56718543; called by muse, mutect2, varscan2
- NTMT1 | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1448210632, COSV52964667; called by muse, mutect2
- PA2G4 | c.645del p.A216Lfs*42 | Frame Shift Del (DEL) | VAF 47/169 reads (28%) | catalogued as rs34197050; called by mutect2, pindel, varscan2
- PHLDB2 | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 38/692 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67309680; called by muse, mutect2
- PLA2G4C | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374191136; called by muse, mutect2, varscan2
- RSL1D1 | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV63077585; called by muse, mutect2, varscan2
- SLC30A3 | c.1159dup p.Q387Pfs*27 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | catalogued as rs747206800; called by mutect2, varscan2
- SLC47A1 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 43/274 reads (16%) | catalogued as COSV54499818; called by muse, mutect2, varscan2
- SNRNP25 | c.326G>T p.R109I (on ENST00000383018; = p.R100I on NM_024571.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51954402; called by muse, mutect2, varscan2
- TM9SF4 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54105701; called by muse, mutect2, varscan2
- ZNRF4 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55773492; called by muse, mutect2
- ADAMTS2 | c.2048A>G p.K683R | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT tolerated (0.73); PolyPhen benign (0.033); called by mutect2, varscan2
- CNOT1 | c.3639+2_3639+3del p.X1213_splice | Splice Site (DEL) | VAF 30/110 reads (27%) | called by pindel, varscan2
- ABCB7 | c.1431G>T p.V477= (on ENST00000373394 / NM_001271696.3; = p.V478= on NM_004299.6) | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV53718910, COSV53721145; called by muse, mutect2
- B3GNT3 | c.723C>T p.N241= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs1476091380, COSV57952985; called by muse, mutect2, varscan2
- DNAAF1 | c.1272G>A p.S424= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs772170131, COSV57576413; called by muse, mutect2, varscan2
- ETV3L | c.1071C>A p.P357= | Silent (SNP) | VAF 124/279 reads (44%) | catalogued as COSV71901019; called by muse, mutect2, varscan2
- F10 | c.852C>T p.F284= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs5959; called by muse, mutect2, varscan2
- G6PC3 | c.480G>A p.S160= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as rs145419406; called by muse, mutect2, varscan2
- IMPG2 | c.2883G>A p.V961= | Silent (SNP) | VAF 26/610 reads (4%) | catalogued as rs1272965154, COSV51975835; called by muse, mutect2
- ITGB4 | c.3060G>A p.G1020= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV52323574; called by muse, varscan2
- KLHL23 | c.1332C>T p.N444= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs539851773, COSV55866432; called by mutect2, varscan2
- NMRAL1 | c.738C>T p.Y246= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs1042004045, COSV52059537; called by muse, mutect2, varscan2
- NTNG2 | c.549C>T p.R183= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs764857818, COSV62364857; called by muse, mutect2, varscan2
- ORMDL3 | c.186C>T p.I62= | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as COSV58345724; called by muse, mutect2, varscan2
- OVGP1 | c.283C>T p.L95= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV63858040; called by muse, mutect2, varscan2
- PGPEP1L | c.141G>A p.P47= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs777566759, COSV66708986; called by muse, mutect2, varscan2
- POLR1F | c.309A>T p.G103= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as COSV55998109; called by muse, mutect2
- PRKCB | c.1563C>T p.S521= | Silent (SNP) | VAF 13/245 reads (5%) | catalogued as rs1002872729, COSV57772830; called by muse, mutect2
- TRUB2 | c.753C>G p.V251= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs368076562, COSV65759483; called by muse, varscan2
